FM case AD3422 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/71c49b30-7a04-4731-a549-5118d5983d6c

Female, 30.9 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the female genital tract; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
